HCMI case HCM-WCMC-1280-C54 — NCI Cancer Model Development for the Human Cancer Model Initiative (HCMI-CMDC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas; Primary site: Corpus uteri. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/cc86271e-34bc-4f3a-bd1b-9200a606a3fa

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Year of birth: 1953; Vital status: Alive.

Diagnoses (1)
1. Endometrioid adenocarcinoma, NOS: ICD-O-3 morphology code: 8380/3; ICD-10 code: C54.1; Tissue or organ of origin: Endometrium; Site of resection or biopsy: Endometrium; Classification of tumor: primary; Age at diagnosis: 63.1 years (23,032 days); AJCC staging edition: 8th; AJCC pathologic T: T1a; AJCC pathologic N: N0; AJCC pathologic stage: Stage IA; FIGO stage: Stage IA; Tumor grade: G3; Metastasis at diagnosis: No Metastasis; Prior malignancy: no; Prior treatment: No; Sites of involvement: Uterus.
   Pathology details: Lymph node involvement: Negative; Tumor largest dimension diameter: 2.1 cm.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Initial Diagnosis; Days to treatment start: 23 days.
   Treatment given: Treatment type: Hormone Therapy; Therapeutic agents: Anastrozole; Treatment intent type: Adjuvant; Initial disease status: Residual Disease; Days to treatment start: 76 days; Days to treatment end: 188 days.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Carboplatin + Paclitaxel; Treatment intent type: Adjuvant; Initial disease status: Residual Disease; Days to treatment start: 76 days; Days to treatment end: 188 days.
   Treatment given: Treatment type: Radiation Therapy, NOS; Treatment intent type: Adjuvant; Initial disease status: Residual Disease; Days to treatment start: 83 days; Days to treatment end: 111 days.
   Recorded as not given: neoadjuvant treatment (type not reported); adjuvant Immunotherapy (Including Vaccines), for residual disease; adjuvant Targeted Molecular Therapy, for residual disease.

Follow-up (1 entry)
- Days to follow up: 1,973 days (5.4 years); Disease response: Complete Response; Progression or recurrence: No.

Molecular and laboratory tests
- CDKN2A (IHC): Equivocal.
- ESR1 (IHC): Positive.
- MLH1 (IHC): Positive.
- MSH2 (IHC): Positive.
- MSH6 (IHC): Positive.
- PGR (IHC): Negative.
- PMS2 (IHC): Positive.
- TP53 (IHC): Overexpressed.
- Test (Microsatellite Analysis): Negative.
- Test: Negative; Mismatch repair mutation: Yes.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 54 kg; Height: 152.4 cm; BMI: 23.
- Timepoint category: Prior to Diagnosis; Comorbidities: Cancer / Endometriosis; Risk factors: Oral Contraceptives / Cancer / Endometriosis.

Exposures
- Tobacco smoking status: Lifelong Non-Smoker.

Family history
- Relative with cancer history: yes; Relationship type: First Degree Relative, NOS; Relationship primary diagnosis: Cancer.

Biospecimens (2 samples)
- Sample HCM-WCMC-1280-C54-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Buffy Coat; Preservation method: Frozen.
- Sample HCM-WCMC-1280-C54-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen.
